Somatic mutation profile of tumor specimen TCGA-FG-8191-01A (aliquot TCGA-FG-8191-01A-11D-2253-08) from TCGA case TCGA-FG-8191, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 30.8 years (11,252 days).
Specimen TCGA-FG-8191-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c59e826f-92c6-41a5-814b-8b859388bab3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-8191-10A (Blood Derived Normal), aliquot TCGA-FG-8191-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ca7e5fc-ade9-4b81-bc89-3ad22273c4c9

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Splice Site 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 40/53 reads (75%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 63/96 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781642, COSV52677695, COSV53351693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP11A | c.862+1G>C p.X288_splice | Splice Site (SNP) | VAF 8/122 reads (7%) | catalogued as COSV64380889; called by muse, mutect2
- DST | c.10358T>C p.M3453T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV99753829; called by mutect2, varscan2
- EML5 | c.4647C>G p.S1549R (on ENST00000380664; = p.S1557R on NM_183387.3) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as COSV61344967; called by muse, mutect2, varscan2
- FAM189A2 | c.856+1G>T p.X286_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as COSV57384554; called by muse, mutect2, varscan2
- GPATCH8 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV59194606; called by muse, mutect2, varscan2
- IBTK | c.2680T>C p.S894P | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV60392594; called by muse, mutect2, varscan2
- KLHL14 | c.948-1G>T p.X316_splice | Splice Site (SNP) | VAF 12/86 reads (14%) | catalogued as COSV63832141; called by muse, mutect2, varscan2
- NID1 | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767149099, COSV51619221; called by muse, mutect2, varscan2
- NKX3-1 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV66512007; called by muse, mutect2, varscan2
- OR5K4 | c.682A>T p.M228L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs1329468016, COSV61583726; called by muse, mutect2
- PRKCA | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750145950, COSV52583433; called by muse, mutect2, varscan2
- PSG1 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV54948706; called by muse, varscan2
- RYR2 | c.4073G>A p.R1358H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV63682271; called by muse, mutect2, varscan2
- SEC16B | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); catalogued as rs1186772036, COSV57624369; called by muse, mutect2, varscan2
- SLC35F1 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64502500; called by muse, mutect2
- SNX18 | c.1576C>G p.Q526E | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1242920966, COSV57988990; called by muse, mutect2
- ZMYM6 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs752388925, COSV64120791; called by muse, mutect2, varscan2
- CAPN15 | c.1230C>T p.P410= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs779633303, COSV54835535; called by muse, mutect2, varscan2
- EPHB6 | c.597G>A p.E199= | Silent (SNP) | VAF 16/353 reads (5%) | catalogued as COSV67418354; called by muse, mutect2
- LRP1B | c.4821C>T p.D1607= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs372242789; called by muse, mutect2, varscan2
- MTNR1B | c.408T>C p.I136= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs1283890113, COSV57066312; called by muse, mutect2, varscan2
- MYO3A | c.2367A>G p.L789= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs750512763, COSV56328949; called by muse, mutect2, varscan2
- SPDYC | c.402A>G p.P134= | Silent (SNP) | VAF 51/148 reads (34%) | catalogued as rs779583712, COSV65865146; called by muse, mutect2, varscan2
- ZNF761 | c.1170C>G p.T390= | Silent (SNP) | VAF 16/191 reads (8%) | catalogued as COSV61888176; called by muse, mutect2
